Somatic mutation profile of tumor specimen TARGET-30-PAIPGU-01A (aliquot TARGET-30-PAIPGU-01A-01W) from TARGET case TARGET-30-PAIPGU, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Age at diagnosis: 2.5 years (898 days).
Specimen TARGET-30-PAIPGU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff84d0f8-8bbb-441c-9e43-42172013bebf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAIPGU-10A (Blood Derived Normal), aliquot TARGET-30-PAIPGU-10A-01W; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ef00da2-9446-40d6-829f-cdbf32d4723b

The open-access MAF lists 44 somatic variants for this specimen: 36 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 5, Nonsense Mutation 3, RNA 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 107/245 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55876538, COSV55894288; called by muse, mutect2, varscan2
- CD53 | c.152C>T p.T51M | Missense Mutation (SNP) | VAF 292/652 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs200779902, COSV54761862; called by muse, mutect2, varscan2
- CFAP44 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 329/901 reads (37%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV55608295; called by muse, mutect2, varscan2
- CPAMD8 | c.1457C>T p.P486L (on ENST00000651564; = p.P439L on NM_015692.5) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.16); PolyPhen probably damaging (1); catalogued as rs761522063, COSV52230706; called by muse, mutect2, varscan2
- DENND3 | c.1813G>T p.A605S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV52800587; called by muse, mutect2, varscan2
- ECPAS | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 119/270 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV52190971; called by muse, mutect2
- ERI3 | c.652C>A p.Q218K | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.75); PolyPhen benign (0.045); catalogued as COSV64830055; called by muse, mutect2, varscan2
- ERMARD | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 31/318 reads (10%) | catalogued as rs973561644, COSV64649263; called by muse, mutect2, varscan2
- GALNT13 | c.1435G>A p.D479N | Missense Mutation (SNP) | VAF 133/298 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as COSV67209065; called by muse, mutect2, varscan2
- INTS5 | c.731C>G p.S244C | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV57950186; called by muse, mutect2, varscan2
- IP6K1 | c.707C>T p.A236V | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as rs753436945, COSV57694778; called by muse, mutect2, varscan2
- IRF6 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 217/488 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV65418603, COSV65418619; called by muse, mutect2
- KRT34 | c.1159G>A p.V387M | Missense Mutation (SNP) | VAF 238/987 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as rs148769355; called by muse, mutect2, varscan2
- MAGEA4 | c.794G>C p.S265T | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.21); catalogued as COSV52340079; called by muse, mutect2, varscan2
- MPZL3 | c.170C>A p.T57N | Missense Mutation (SNP) | VAF 371/457 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV54052517; called by muse, mutect2
- NXPE3 | c.1571G>T p.W524L | Missense Mutation (SNP) | VAF 19/345 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99839649; called by muse, mutect2
- OR51G2 | c.914G>T p.R305L | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV58991743, COSV58993153; called by muse, mutect2, varscan2
- RASGRP1 | c.2159G>T p.R720I | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.929); catalogued as COSV100172265, COSV60363568; called by muse, mutect2, varscan2
- RIMS3 | c.571C>T p.P191S | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV65503824; called by muse, mutect2, varscan2
- RP1L1 | c.5705A>T p.E1902V | Missense Mutation (SNP) | VAF 153/368 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.051); catalogued as COSV66751426; called by muse, mutect2, varscan2
- SCGB2B2 | c.61G>T p.G21W | Missense Mutation (SNP) | VAF 60/156 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as COSV64857055; called by muse, mutect2, varscan2
- SI | c.2581G>C p.V861L | Missense Mutation (SNP) | VAF 70/157 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV52264977; called by muse, mutect2, varscan2
- SLC16A6 | c.1008G>T p.M336I | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.211); catalogued as COSV59176100; called by muse, mutect2, varscan2
- STAG1 | c.2261A>G p.D754G | Missense Mutation (SNP) | VAF 72/160 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV52600215; called by muse, varscan2
- SYNE2 | c.3541G>T p.E1181* | Nonsense Mutation (SNP) | VAF 45/174 reads (26%) | catalogued as COSV59938724; called by muse, mutect2, varscan2
- TAS2R30 | c.290G>T p.W97L | Missense Mutation (SNP) | VAF 23/584 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV67859534; called by muse, mutect2
- TRIM48 | c.193C>A p.L65I | Missense Mutation (SNP) | VAF 75/294 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0.26); catalogued as rs763093051, COSV70160708, COSV70161441; called by muse, mutect2, varscan2
- USP36 | c.1138G>T p.A380S | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.755); catalogued as COSV61750039; called by muse, mutect2, varscan2
- ZBTB7C | c.1302C>A p.D434E | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV59687549; called by muse, mutect2, varscan2
- COL21A1 | c.1499G>T p.G500V | Missense Mutation (SNP) | VAF 49/686 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GCLC | c.685G>T p.A229S (on ENST00000643939; = p.A227S on NM_001498.4) | Missense Mutation (SNP) | VAF 19/369 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.012); called by muse, mutect2
- ILK | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 63/178 reads (35%) | called by muse, mutect2, varscan2
- ILK | c.458A>T p.E153V | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IMPG2 | c.2632G>C p.V878L | Missense Mutation (SNP) | VAF 29/329 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2
- PRG4 | c.165G>C p.E55D | Missense Mutation (SNP) | VAF 54/566 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2
- TADA2A | c.364C>A p.P122T | Missense Mutation (SNP) | VAF 180/399 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- ADAM21 | c.2061T>C p.I687= | Silent (SNP) | VAF 91/158 reads (58%) | catalogued as COSV50788645; called by muse, mutect2, varscan2
- EIF3I | c.315C>A p.G105= | Silent (SNP) | VAF 52/108 reads (48%) | catalogued as COSV59083909; called by muse, mutect2, varscan2
- HPD | c.924C>T p.I308= | Silent (SNP) | VAF 55/97 reads (57%) | catalogued as COSV56640874; called by muse, mutect2, varscan2
- HSD17B10 | c.708C>T p.L236= | Silent (SNP) | VAF 171/290 reads (59%) | catalogued as rs782783783, COSV51447394; called by muse, mutect2, varscan2
- ZNF426 | c.639A>T p.V213= | Silent (SNP) | VAF 60/505 reads (12%) | catalogued as COSV53468228; called by muse, mutect2, varscan2
- GPRC5A | c.*3376C>A | 3'UTR (SNP) | VAF 11/117 reads (9%) | catalogued as rs1170983634; called by muse, mutect2
- SLC47A1 | c.921+1555G>T | Intron (SNP) | VAF 79/225 reads (35%) | catalogued as COSV99565678; called by muse, mutect2, varscan2
- STAG3L4 | n.723C>A | RNA (SNP) | VAF 13/96 reads (14%) | called by muse, mutect2, varscan2
